Somatic mutation profile of tumor specimen C3N-02713-03 (aliquot CPT0190850006) from CPTAC case C3N-02713, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 64.9 years (23,707 days).
Specimen C3N-02713-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc19df7f-869a-4d78-9b32-1bf7e61f6405.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02713-71 (Blood Derived Normal), aliquot CPT0190950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ead53e56-cf17-42c2-a0cb-3607323e8438

The open-access MAF lists 722 somatic variants for this specimen: 506 protein-altering or splice-affecting, 134 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 436, Silent 134, Intron 40, Nonsense Mutation 33, RNA 15, Splice Site 13, 3'UTR 13, Frame Shift Del 12, Frame Shift Ins 6, 5'Flank 6, Splice Region 5, 5'UTR 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.96+1G>T p.X32_splice | Splice Site (SNP) | VAF 133/252 reads (53%) | hotspot (GDC flag); catalogued as rs1131691003, CS167193, COSV52662718, COSV52757202, COSV53162510; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.3083A>G p.H1028R | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs750955315; called by muse, mutect2, varscan2
- ABCA10 | c.2743C>G p.Q915E | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as rs1291976969; called by muse, mutect2
- ADGRF4 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 73/242 reads (30%) | PolyPhen benign (0); catalogued as rs1338777324; called by muse, mutect2, varscan2
- ALMS1 | c.7868G>A p.R2623K | Missense Mutation (SNP) | VAF 156/446 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV52514607, COSV52520324; called by muse, mutect2, varscan2
- ANKRD30A | c.3734A>G p.N1245S (on ENST00000611781; = p.N1189S on NM_052997.2) | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV64608836; called by muse, mutect2, varscan2
- ANKRD30B | c.1735-1G>T p.X579_splice | Splice Site (SNP) | VAF 27/104 reads (26%) | catalogued as COSV62812578; called by muse, mutect2, varscan2
- ANKRD55 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/172 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs757338639; called by muse, mutect2
- APBA1 | c.1445G>C p.R482P | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367760423; called by muse, mutect2, varscan2
- ARHGAP10 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753824577, COSV100331603; called by muse, mutect2, varscan2
- ATP7B | c.3903+2T>G p.X1301_splice | Splice Site (SNP) | VAF 204/646 reads (32%) | catalogued as CS068303; called by mutect2, varscan2
- B3GALT1 | c.35C>A p.T12K | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as COSV59907924; called by muse, varscan2
- BCO1 | c.188G>C p.R63T | Missense Mutation (SNP) | VAF 236/376 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV50732604, COSV99258810; called by muse, mutect2, varscan2
- BNC2 | c.2842G>C p.G948R | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV66163117; called by muse, mutect2, varscan2
- C12orf60 | c.65A>T p.H22L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV57453552; called by muse, mutect2, varscan2
- C6 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 106/654 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV54717152; called by muse, mutect2, varscan2
- C6orf118 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 37/266 reads (14%) | catalogued as COSV57817327; called by muse, mutect2, varscan2
- CADM2 | c.148G>T p.D50Y (on ENST00000407528 / NM_001167674.2; = p.D52Y on NM_153184.4) | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101055263; called by muse, mutect2, varscan2
- CAPN5 | c.919G>A p.G307S (on ENST00000456580; = p.G267S on NM_004055.5) | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.441); catalogued as rs782755981, COSV53685592; called by muse, mutect2, varscan2
- CAPN5 | c.920G>A p.G307D (on ENST00000456580; = p.G267D on NM_004055.5) | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV53689230; called by muse, mutect2, varscan2
- CCDC185 | c.1022del p.P341Rfs*84 | Frame Shift Del (DEL) | VAF 39/316 reads (12%) | catalogued as rs1464247668; called by mutect2, varscan2
- CCL13 | c.195C>G p.F65L | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56774574, COSV99861654; called by muse, mutect2
- CDC42BPA | c.4267T>C p.Y1423H (on ENST00000334218 / NM_001366019.2; = p.Y1410H on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs776936556; called by muse, mutect2
- CDCP1 | c.1331A>G p.H444R | Missense Mutation (SNP) | VAF 130/251 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99943866; called by muse, mutect2, varscan2
- CDCP2 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 197/305 reads (65%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100313226, COSV61284606; called by muse, mutect2, varscan2
- CDH19 | c.1902C>A p.F634L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.433); catalogued as COSV50961634; called by muse, mutect2, varscan2
- CDH19 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100052338; called by muse, mutect2
- CDH9 | c.2172C>A p.D724E | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50261778; called by muse, mutect2, varscan2
- CEACAM18 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760238597, COSV101140125; called by muse, mutect2, varscan2
- CENPF | c.1543T>A p.C515S | Missense Mutation (SNP) | VAF 105/218 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV65275574; called by muse, mutect2, varscan2
- CNKSR3 | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs747490306; called by muse, mutect2, varscan2
- CNTNAP5 | c.538G>C p.V180L | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV101443070; called by muse, mutect2, varscan2
- COG3 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.462); catalogued as COSV63072540; called by muse, mutect2, varscan2
- COL15A1 | c.2794G>T p.G932C | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66641144; called by muse, mutect2, varscan2
- CORO6 | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100801249, COSV61471331; called by muse, mutect2, varscan2
- CSN3 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100515327; called by muse, mutect2, varscan2
- CTDP1 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 73/298 reads (24%) | catalogued as COSV50006281; called by muse, mutect2, varscan2
- CTNNA2 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 245/383 reads (64%) | catalogued as COSV100785273; called by muse, mutect2, varscan2
- CTTN | c.1333G>T p.V445L | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV57234068; called by muse, mutect2, varscan2
- CUBN | c.10863G>A p.W3621* | Nonsense Mutation (SNP) | VAF 128/395 reads (32%) | catalogued as COSV100913237; called by muse, mutect2, varscan2
- DDC | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs752108612, COSV63564210, COSV63568522; called by muse, mutect2
- DLGAP2 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1417602336, COSV70100267; called by muse, mutect2, varscan2
- DNAH1 | c.9363G>T p.K3121N | Missense Mutation (SNP) | VAF 184/371 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV70228995, COSV70231095; called by muse, mutect2, varscan2
- DNAH6 | c.7970G>A p.R2657H | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs931999477, COSV52873883; called by muse, mutect2, varscan2
- DOCK2 | c.3078G>T p.W1026C | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56946591; called by muse, mutect2, varscan2
- DYNC2H1 | c.5614G>T p.V1872F | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62092102; called by muse, mutect2, varscan2
- EPC1 | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53923041; called by muse, mutect2, varscan2
- FAM120B | c.2596G>T p.A866S | Missense Mutation (SNP) | VAF 176/387 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV53008798; called by muse, mutect2, varscan2
- FAM47A | c.973C>A p.L325I | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1204433594; called by muse, varscan2
- FAT4 | c.7267G>A p.A2423T | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs776977766, COSV58679491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN3 | c.5669G>A p.C1890Y | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs183344960; called by muse, mutect2, varscan2
- FEN1 | c.880G>C p.V294L | Missense Mutation (SNP) | VAF 70/317 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV57251420; called by muse, mutect2, varscan2
- FOS | c.322A>T p.R108W | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV57839097; called by muse, mutect2, varscan2
- FOXI3 | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 207/326 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67916788; called by muse, mutect2, varscan2
- GIPC1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs370004452; called by muse, mutect2, varscan2
- GLIS1 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV56552044; called by muse, mutect2, varscan2
- GMPR | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs374348859; called by muse, mutect2, varscan2
- GPHB5 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 163/350 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs757997304; called by muse, mutect2, varscan2
- GPR20 | c.952C>G p.R318G | Missense Mutation (SNP) | VAF 54/558 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100897314; called by muse, mutect2
- GRB10 | c.1474C>T p.H492Y (on ENST00000398812; = p.H446Y on NM_001001549.3) | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.107); catalogued as rs747290685; called by muse, mutect2, varscan2
- GRIA4 | c.858G>C p.E286D | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.569); catalogued as COSV56882539; called by muse, mutect2, varscan2
- H4C9 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 49/412 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as CM142425; called by muse, mutect2, varscan2
- HEXA | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 151/752 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99173706; called by muse, mutect2, varscan2
- HSD17B1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 209/677 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1364351727, COSV99864864; called by muse, mutect2, varscan2
- HTR1B | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 67/349 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as rs1273517791; called by muse, mutect2, varscan2
- IDO2 | c.488G>T p.S163I (on ENST00000389060; = p.S176I on NM_194294.2) | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV58426403; called by muse, mutect2, varscan2
- IGHV3-66 | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 50/510 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1327577136; called by mutect2, varscan2
- IGHV5-51 | c.309C>A p.S103R | Missense Mutation (SNP) | VAF 79/626 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs180672762; called by muse, mutect2, varscan2
- IGKV1D-8 | c.65G>A p.C22Y | Missense Mutation (SNP) | VAF 37/542 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as rs367822287; called by muse, mutect2
- IL10RA | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs754224918; called by muse, mutect2, varscan2
- IL1RAPL1 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56262981; called by muse, varscan2
- ILDR2 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 72/494 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1377515280, COSV54829340; called by muse, mutect2, varscan2
- INTS1 | c.5849G>A p.R1950H | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV104431348, COSV67176617; called by muse, mutect2, varscan2
- IQCN | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 81/426 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs1302945771; called by muse, mutect2, varscan2
- JHY | c.2266G>T p.E756* | Nonsense Mutation (SNP) | VAF 103/273 reads (38%) | catalogued as COSV57079051; called by muse, mutect2, varscan2
- KCMF1 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769032909; called by muse, mutect2, varscan2
- KLHL1 | c.403T>C p.F135L | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1043956430; called by muse, mutect2, varscan2
- KMT5C | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 144/374 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs1222888821, COSV55319690; called by muse, mutect2, varscan2
- KRTAP5-7 | c.241G>T p.G81W | Missense Mutation (SNP) | VAF 104/579 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs755569464; called by muse, mutect2, varscan2
- LAMA2 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 116/284 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs753382270; called by muse, mutect2, varscan2
- LEMD3 | c.349A>G p.S117G | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs886049774; ClinVar: uncertain significance; called by muse, varscan2
- LGSN | c.1013C>A p.T338K | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs372668010; called by muse, mutect2, varscan2
- LRRC43 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 84/398 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.726); catalogued as rs1282606763, COSV60290684; called by muse, mutect2, varscan2
- MALRD1 | c.4559C>A p.S1520Y | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66002955; called by muse, mutect2, varscan2
- MAP3K19 | c.800C>A p.A267D | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV59639347; called by muse, mutect2, varscan2
- MECOM | c.2647C>G p.Q883E (on ENST00000468789 / NM_001105078.4; = p.Q1071E on NM_004991.4) | Missense Mutation (SNP) | VAF 59/1710 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV52959493; called by muse, mutect2
- MMP16 | c.872-1G>A p.X291_splice | Splice Site (SNP) | VAF 45/92 reads (49%) | catalogued as COSV99686299; called by muse, mutect2, varscan2
- MON2 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 133/328 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs1261726911, COSV99742788; called by muse, mutect2, varscan2
- MUC16 | c.31817C>T p.T10606I | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV101199451; called by muse, mutect2, varscan2
- NAV3 | c.1736G>T p.C579F | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV57104978; called by muse, mutect2, varscan2
- NBEA | c.3574G>A p.G1192S | Missense Mutation (SNP) | VAF 92/193 reads (48%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs540004972, COSV100080843; called by muse, mutect2, varscan2
- NBPF12 | c.3055G>A p.D1019N | Missense Mutation (SNP) | VAF 73/845 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs1466660131; called by muse, mutect2, varscan2
- NCAM2 | c.2078-1G>T p.X693_splice | Splice Site (SNP) | VAF 48/108 reads (44%) | catalogued as rs1211007072; called by muse, mutect2, varscan2
- NCKAP1L | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as rs1320196891; called by muse, mutect2, varscan2
- NIPAL2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs1373358689; called by muse, mutect2, varscan2
- NKX2-4 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 111/513 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1443027170; called by muse, mutect2, varscan2
- NLRP12 | c.2911A>G p.R971G | Missense Mutation (SNP) | VAF 93/372 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs753280591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP2 | c.2507G>C p.R836T | Missense Mutation (SNP) | VAF 240/697 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV54761683; called by muse, mutect2, varscan2
- NRAP | c.4174C>T p.P1392S (on ENST00000359988 / NM_001322945.2; = p.P1357S on NM_006175.4) | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as rs1382439597; called by muse, mutect2, varscan2
- NRSN2 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV101206804; called by muse, mutect2, varscan2
- NT5DC4 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.787); catalogued as COSV100559916; called by muse, mutect2, varscan2
- OAS3 | c.1219G>C p.D407H | Missense Mutation (SNP) | VAF 72/429 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as rs773065715; called by muse, mutect2, varscan2
- OR2AJ1 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV59089941; called by muse, mutect2
- OR2T10 | c.278C>G p.S93W | Missense Mutation (SNP) | VAF 305/354 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57896065; called by muse, mutect2, varscan2
- OR2T33 | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 262/1280 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs769398760; called by muse, mutect2, varscan2
- OSMR | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 60/436 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99952916; called by muse, varscan2
- PC | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 52/436 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs781568566, COSV100852247; called by muse, varscan2
- PDCD11 | c.5316T>G p.F1772L | Missense Mutation (SNP) | VAF 80/133 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766302691; called by muse, mutect2, varscan2
- PIK3C2G | c.890C>A p.S297* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as COSV56835434, COSV56840296; called by muse, mutect2, varscan2
- PM20D1 | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372481740, COSV65648606; called by muse, mutect2
- POM121L12 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 56/295 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs767476421, COSV101374867; called by muse, mutect2, varscan2
- POT1 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as rs1342019926; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR29 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs757581978; called by muse, mutect2, varscan2
- PRTG | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs764418980, COSV66837366; called by muse, mutect2, varscan2
- PSMB3 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs1224894009; called by muse, mutect2, varscan2
- PTDSS2 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 56/455 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs376070131; called by muse, mutect2, varscan2
- RARRES2 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs372205459; called by muse, mutect2, varscan2
- RBM42 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.582); catalogued as COSV52898416; called by muse, mutect2, varscan2
- RELN | c.3593G>T p.R1198L | Missense Mutation (SNP) | VAF 231/535 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs114655373; called by muse, mutect2, varscan2
- RET | c.1753T>G p.C585G | Missense Mutation (SNP) | VAF 595/1184 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100392812; called by muse, mutect2, varscan2
- RIMS3 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 79/146 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101013399; called by muse, mutect2, varscan2
- RP1L1 | c.1548G>T p.E516D | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1267095620; called by muse, mutect2, varscan2
- RPE65 | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777966849; called by muse, mutect2, varscan2
- RUNX1T1 | c.261G>T p.L87F (on ENST00000265814 / NM_001198628.1; = p.L60F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs757554284; called by muse, mutect2, varscan2
- SALL1 | c.3651C>A p.F1217L | Missense Mutation (SNP) | VAF 113/683 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV51760763; called by muse, mutect2, varscan2
- SAP30 | c.68T>G p.V23G | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV56635101; called by muse, mutect2, varscan2
- SCAF1 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs549032915; called by muse, mutect2, varscan2
- SCN5A | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 33/149 reads (22%) | catalogued as COSV100346442; called by muse, mutect2, varscan2
- SEMA3D | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV99405947; called by muse, mutect2, varscan2
- SLC17A4 | c.397G>T p.G133* | Nonsense Mutation (SNP) | VAF 143/471 reads (30%) | catalogued as COSV100930678; called by muse, mutect2, varscan2
- SLC27A4 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 112/398 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as rs200595810; called by muse, mutect2, varscan2
- SLC45A2 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 28/494 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as rs762813061, CM101006; called by muse, mutect2
- SLC6A5 | c.2241G>T p.R747S | Missense Mutation (SNP) | VAF 121/369 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV54224156; called by muse, mutect2, varscan2
- SLC7A13 | c.197G>A p.C66Y | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1443654895; called by muse, mutect2, varscan2
- SMARCA2 | c.4138C>T p.P1380S | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs1459862670; called by muse, mutect2, varscan2
- SMPD1 | c.677C>G p.P226R | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1017798566; called by muse, mutect2, varscan2
- SON | c.6400G>A p.E2134K | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99280021; called by muse, mutect2, varscan2
- SPAM1 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 35/264 reads (13%) | catalogued as COSV99773359; called by muse, mutect2, varscan2
- SPG7 | c.2159C>T p.A720V (on ENST00000268704; = p.A727V on NM_003119.4) | Missense Mutation (SNP) | VAF 29/621 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs760043860; ClinVar: uncertain significance; called by muse, mutect2
- SPNS2 | c.1466G>A p.S489N | Missense Mutation (SNP) | VAF 99/177 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1315886133; called by muse, mutect2, varscan2
- SPTB | c.4002G>A p.A1334= | Splice Region (SNP) | VAF 109/519 reads (21%) | catalogued as rs755683215; called by muse, mutect2, varscan2
- STAB2 | c.4787G>A p.R1596H | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as rs140998727; called by muse, mutect2, varscan2
- SULT1C3 | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV61253490, COSV61254203; called by muse, varscan2
- SUPT20H | c.1219A>G p.N407D (on ENST00000350612 / NM_001014286.3; = p.N408D on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs771572445; called by muse, mutect2, varscan2
- TAAR5 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV57798887; called by muse, mutect2, varscan2
- TBC1D10A | c.518dup p.H174Pfs*40 | Frame Shift Ins (INS) | VAF 42/316 reads (13%) | catalogued as rs772995689; called by mutect2, varscan2
- TET2 | c.4594C>T p.Q1532* | Nonsense Mutation (SNP) | VAF 13/97 reads (13%) | catalogued as COSV54423959; called by muse, mutect2, varscan2
- TIAM2 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 72/430 reads (17%) | catalogued as COSV59699749; called by muse, mutect2, varscan2
- TMEM132C | c.2809G>T p.A937S | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59433526; called by muse, mutect2
- TMEM135 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.085); catalogued as COSV59704957; called by muse, mutect2, varscan2
- TNFRSF4 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV55419505; called by muse, mutect2, varscan2
- TRIM51GP | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1217605446; called by muse, mutect2, varscan2
- TTN | c.61654G>T p.V20552F (on ENST00000591111; = p.V13128F on NM_003319.4) | Missense Mutation (SNP) | VAF 14/118 reads (12%) | PolyPhen probably damaging (0.999); catalogued as COSV100610296; called by muse, mutect2, varscan2
- TTN | c.16616G>C p.W5539S (on ENST00000591111; = p.W4612S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/351 reads (7%) | PolyPhen probably damaging (0.998); catalogued as COSV59979217; called by muse, mutect2
- UGT2A3 | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as COSV52361602; called by muse, mutect2, varscan2
- UPP1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756580671, COSV57977420, COSV57978492; called by muse, mutect2, varscan2
- VEGFC | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54600431, COSV99039774; called by muse, mutect2, varscan2
- VWDE | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as rs1253832442; called by muse, mutect2, varscan2
- ZBTB45 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs773158376; called by muse, mutect2, varscan2
- ZNF257 | c.98T>C p.M33T | Missense Mutation (SNP) | VAF 130/312 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71306356; called by muse, mutect2, varscan2
- ZNF385D | c.726A>T p.K242N | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55772697, COSV99872841; called by muse, mutect2, varscan2
- ZNF536 | c.2941C>G p.R981G | Missense Mutation (SNP) | VAF 130/415 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV62817560, COSV62818086; called by muse, mutect2, varscan2
- ZNF606 | c.2189A>G p.H730R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775804145; called by muse, mutect2, varscan2
- ZNF804A | c.1049G>C p.G350A | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs895709409; called by muse, mutect2, varscan2
- AAAS | c.1402del p.A468Pfs*83 | Frame Shift Del (DEL) | VAF 141/636 reads (22%) | called by mutect2, pindel, varscan2
- ABCA9 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC11 | c.1649A>T p.K550M | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCG4 | c.1138A>T p.R380W | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABHD18 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACACB | c.3523G>T p.A1175S | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ACOX1 | c.1017T>A p.Y339* | Nonsense Mutation (SNP) | VAF 191/650 reads (29%) | called by muse, mutect2, varscan2
- ADAM19 | c.1594G>T p.G532* | Nonsense Mutation (SNP) | VAF 66/300 reads (22%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.3910A>T p.N1304Y | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADAMTS16 | c.1418C>A p.P473H | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ADGB | c.4270G>T p.E1424* | Nonsense Mutation (SNP) | VAF 40/105 reads (38%) | called by muse, mutect2, varscan2
- ADGRV1 | c.7328G>A p.C2443Y | Missense Mutation (SNP) | VAF 106/209 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADRA1D | c.1573G>A p.G525S | Missense Mutation (SNP) | VAF 191/486 reads (39%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGTRAP | c.351_354dup p.V119Pfs*14 | Frame Shift Ins (INS) | VAF 27/143 reads (19%) | called by mutect2, pindel, varscan2
- AL669918.1 | c.2021C>A p.S674Y | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ALAD | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 125/312 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ALG10B | c.255G>T p.W85C | Missense Mutation (SNP) | VAF 132/421 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ANK1 | c.4267dup p.R1423Pfs*36 | Frame Shift Ins (INS) | VAF 218/631 reads (35%) | called by mutect2, pindel, varscan2
- ANKS6 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ANXA3 | c.665A>T p.K222M | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- APOB | c.10016A>G p.Y3339C | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- APP | c.1963+1G>T p.X655_splice | Splice Site (SNP) | VAF 168/414 reads (41%) | called by muse, mutect2, varscan2
- APPL1 | c.755A>T p.E252V | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARGFX | c.206T>C p.V69A | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- ARHGAP44 | c.1718T>A p.L573H | Missense Mutation (SNP) | VAF 87/158 reads (55%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | called by mutect2, varscan2
- ARID4B | c.1921A>G p.I641V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); called by muse, mutect2
- ARL4C | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASTN2 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATAD3A | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 227/446 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATG2A | c.3191T>A p.L1064Q | Missense Mutation (SNP) | VAF 97/230 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BANK1 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- BASP1 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCAM | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BEAN1 | c.47G>C p.S16T | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.194); called by muse, mutect2
- BOD1L1 | c.4968T>A p.S1656R | Missense Mutation (SNP) | VAF 92/314 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BRD3 | c.2023G>A p.V675I | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- BTBD8 | c.4270_4277delinsC p.E1424Lfs*38 (on ENST00000636805 / NM_001376131.1; = p.E911Lfs*38 on NM_015237.4) | Frame Shift Del (DEL) | VAF 21/146 reads (14%) | called by pindel, varscan2*
- C10orf71 | c.2935G>A p.G979S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- C19orf81 | c.58A>G p.R20G | Missense Mutation (SNP) | VAF 73/328 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C6orf58 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- C8B | c.662C>A p.P221Q | Missense Mutation (SNP) | VAF 196/385 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- C9 | c.870+5G>C | Splice Region (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2
- C9orf131 | c.2612A>T p.Q871L | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA2D4 | c.1275C>G p.V425= | Splice Region (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- CAND2 | c.1972G>T p.A658S (on ENST00000456430 / NM_001162499.2; = p.A565S on NM_012298.3) | Missense Mutation (SNP) | VAF 87/499 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- CAPN14 | c.423C>G p.H141Q | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CASP5 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); called by muse, mutect2
- CBX4 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CCAR2 | c.2678G>T p.R893L | Missense Mutation (SNP) | VAF 123/275 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CCDC170 | c.1873A>T p.M625L | Missense Mutation (SNP) | VAF 180/410 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC50 | c.650A>T p.H217L | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCDC50 | c.1367C>T p.T456I (on ENST00000392455 / NM_178335.3; = p.T280I on NM_174908.4) | Missense Mutation (SNP) | VAF 87/467 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- CCDC68 | c.493C>A p.Q165K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CCR4 | c.437T>C p.L146S | Missense Mutation (SNP) | VAF 106/227 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- CDC42SE2 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CDH8 | c.1873A>T p.I625F | Missense Mutation (SNP) | VAF 192/413 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CECR2 | c.1854dup p.R619Afs*79 (on ENST00000342247 / NM_001290047.2; = p.R436Afs*79 on NM_001290046.1) | Frame Shift Ins (INS) | VAF 75/212 reads (35%) | called by mutect2, pindel, varscan2
- CEP120 | c.2081G>C p.R694T | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CERK | c.1568T>C p.F523S | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFAP47 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); called by muse, varscan2
- CILK1 | c.209G>T p.R70M | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CLMN | c.2426C>T p.P809L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNBD1 | c.988T>A p.S330T | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CNTN6 | c.991A>T p.I331F | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- CNTN6 | c.2510G>T p.G837V | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COG3 | c.1282G>T p.G428W | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- COL1A2 | c.2890G>T p.G964C | Missense Mutation (SNP) | VAF 337/1133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL27A1 | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL5A1 | c.1675G>A p.G559R | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPEB4 | c.1547-2A>G p.X516_splice | Splice Site (SNP) | VAF 61/249 reads (24%) | called by muse, mutect2, varscan2
- CPLX2 | c.270C>A p.C90* | Nonsense Mutation (SNP) | VAF 92/160 reads (58%) | called by muse, mutect2, varscan2
- CPSF1 | c.1180C>T p.L394F | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CPXM2 | c.1908C>A p.F636L | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CRACR2A | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRYM | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 93/543 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CSMD3 | c.6211G>T p.G2071* (on ENST00000297405 / NM_001363185.1; = p.G1967* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 104/403 reads (26%) | called by muse, mutect2, varscan2
- CTNND2 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 129/407 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CTNND2 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); called by muse, mutect2
- CTTNBP2 | c.2273-1G>T p.X758_splice | Splice Site (SNP) | VAF 22/183 reads (12%) | called by muse, mutect2, varscan2
- DAPK1 | c.822G>T p.W274C | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF12L1 | c.169G>T p.V57F | Missense Mutation (SNP) | VAF 200/272 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DEFB121 | c.208C>A p.L70M | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- DGKK | c.2594G>C p.G865A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DMD | c.6488A>T p.N2163I | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- DMPK | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 110/265 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH5 | c.10727G>T p.W3576L | Missense Mutation (SNP) | VAF 173/450 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH5 | c.1475C>G p.T492R | Missense Mutation (SNP) | VAF 64/540 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DOCK1 | c.4520T>C p.M1507T | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- DPP6 | c.2553C>A p.D851E (on ENST00000377770 / NM_001364500.2; = p.D789E on NM_001936.5) | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- DPY19L2 | c.862-2A>T p.X288_splice | Splice Site (SNP) | VAF 93/230 reads (40%) | called by muse, mutect2, varscan2
- DYSF | c.3392C>G p.S1131C | Missense Mutation (SNP) | VAF 70/631 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EDEM1 | c.1270A>T p.N424Y | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- EEF1D | c.217A>T p.T73S | Missense Mutation (SNP) | VAF 49/411 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EGR3 | c.122A>T p.D41V | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ELP1 | c.1575del p.S526Lfs*6 | Frame Shift Del (DEL) | VAF 41/279 reads (15%) | called by mutect2, pindel, varscan2
- EML5 | c.2810A>C p.K937T | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENTHD1 | c.656C>G p.T219S | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPB41L5 | c.613T>C p.W205R | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPHB1 | c.1669del p.V557Wfs*35 | Frame Shift Del (DEL) | VAF 30/290 reads (10%) | called by mutect2, pindel, varscan2
- ESYT2 | c.2172G>T p.E724D (on ENST00000613624; = p.E648D on NM_020728.3) | Missense Mutation (SNP) | VAF 114/288 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ESYT2 | c.2171A>T p.E724V (on ENST00000613624; = p.E648V on NM_020728.3) | Missense Mutation (SNP) | VAF 110/282 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ETNK1 | c.428G>C p.R143P | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- EYA1 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 19/277 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- FAM135B | c.3407A>G p.E1136G | Missense Mutation (SNP) | VAF 69/445 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM234B | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM8A1 | c.520C>G p.P174A | Missense Mutation (SNP) | VAF 54/330 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- FAM90A10P | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 133/998 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- FAT1 | c.12350C>A p.S4117* | Nonsense Mutation (SNP) | VAF 82/313 reads (26%) | called by muse, mutect2, varscan2
- FAT3 | c.12980G>C p.G4327A | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXO2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 288/565 reads (51%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FBXO45 | c.554A>T p.Y185F | Missense Mutation (SNP) | VAF 264/548 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- FKBP8 | c.1103T>A p.L368Q (on ENST00000222308 / NM_001308373.2; = p.L369Q on NM_012181.5) | Missense Mutation (SNP) | VAF 75/356 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FLRT2 | c.1313A>G p.Q438R | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2
- FMNL3 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 79/245 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FNIP2 | c.1708A>G p.I570V | Missense Mutation (SNP) | VAF 88/567 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXF2 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 86/574 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FPGS | c.122C>A p.P41Q | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- FPR2 | c.711C>A p.S237R | Missense Mutation (SNP) | VAF 79/288 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- FRMPD2 | c.2432G>T p.G811V | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FSHB | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 73/381 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FSIP2 | c.15837C>A p.D5279E | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- FYCO1 | c.290T>A p.L97H | Missense Mutation (SNP) | VAF 75/393 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FZD10 | c.526A>G p.S176G | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRA6 | c.47del p.N16Mfs*3 | Frame Shift Del (DEL) | VAF 94/384 reads (24%) | called by mutect2, pindel, varscan2
- GAS2 | c.145+1G>T p.X49_splice | Splice Site (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- GLIPR1L1 | c.257C>A p.S86* | Nonsense Mutation (SNP) | VAF 50/152 reads (33%) | called by muse, mutect2, varscan2
- GLRA3 | c.1247A>G p.E416G | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPR85 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GRM7 | c.1602G>C p.K534N | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- HCN1 | c.2317G>C p.A773P | Missense Mutation (SNP) | VAF 97/358 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HCN1 | c.959del p.P320Hfs*14 | Frame Shift Del (DEL) | VAF 50/467 reads (11%) | called by mutect2, pindel, varscan2
- HEATR1 | c.642G>T p.R214S | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEATR4 | c.1359G>A p.W453* | Nonsense Mutation (SNP) | VAF 243/584 reads (42%) | called by muse, mutect2, varscan2
- HHLA1 | c.1583G>T p.C528F | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNMT | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HPCAL1 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 54/412 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HS6ST3 | c.919A>C p.N307H | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IFI16 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IFIH1 | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 55/453 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- IGF2BP1 | c.1385C>G p.A462G | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IGHV3-53 | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 209/725 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- IGKV1-33 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 35/389 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- IGKV1D-33 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 50/741 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.044); called by muse, mutect2
- IL12A | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- INSC | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 96/277 reads (35%) | called by muse, mutect2, varscan2
- KCNC2 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 220/681 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KCNC3 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KCNG2 | c.293C>A p.A98E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNJ1 | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK18 | c.978del p.F326Lfs*6 | Frame Shift Del (DEL) | VAF 244/595 reads (41%) | called by mutect2, pindel, varscan2
- KCNMA1 | c.2987G>T p.G996V (on ENST00000286628 / NM_001161352.2; = p.G938V on NM_002247.4) | Missense Mutation (SNP) | VAF 63/314 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM3A | c.3647G>C p.R1216P | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- KDM4B | c.3181C>T p.P1061S | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KHDRBS3 | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 52/500 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- KIR3DL1 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 96/417 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KMT2E | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRTAP9-7 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 61/809 reads (8%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.794); called by muse, mutect2
- LAMA1 | c.5902G>A p.E1968K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA2 | c.8138A>G p.Q2713R | Missense Mutation (SNP) | VAF 106/305 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- LGMN | c.191A>T p.E64V | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- LPA | c.5104G>T p.A1702S | Missense Mutation (SNP) | VAF 92/508 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRCH2 | c.1497C>G p.N499K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRGUK | c.816G>T p.M272I | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP2 | c.7214C>G p.P2405R | Missense Mutation (SNP) | VAF 146/454 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- LRP2 | c.6841T>A p.Y2281N | Missense Mutation (SNP) | VAF 119/342 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- LRPPRC | c.107C>G p.A36G | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC66 | c.1966G>T p.V656F | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- LRRC9 | c.3284T>C p.M1095T | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LRRN2 | c.2056C>A p.L686I | Missense Mutation (SNP) | VAF 61/351 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRTM4 | c.1555C>G p.P519A | Missense Mutation (SNP) | VAF 193/274 reads (70%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- MAGEB2 | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- MASTL | c.302A>G p.Q101R | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- MATN1 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCM9 | c.802A>G p.I268V | Missense Mutation (SNP) | VAF 111/287 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MEF2D | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- MEP1A | c.365T>G p.F122C | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGAM2 | c.2986C>A p.L996M | Missense Mutation (SNP) | VAF 122/391 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MMP12 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMRN2 | c.2041dup p.S681Kfs*178 | Frame Shift Ins (INS) | VAF 27/100 reads (27%) | called by mutect2, pindel, varscan2
- MUC17 | c.10327G>T p.A3443S | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MUC2 | c.3294C>A p.Y1098* | Nonsense Mutation (SNP) | VAF 69/216 reads (32%) | called by muse, mutect2, varscan2
- MUC5AC | c.16492T>G p.C5498G | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYBPC3 | c.2749G>T p.V917L | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYH15 | c.3934C>A p.Q1312K | Missense Mutation (SNP) | VAF 115/240 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH7B | c.5395G>T p.A1799S | Missense Mutation (SNP) | VAF 110/293 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- MYH8 | c.3031G>A p.D1011N | Missense Mutation (SNP) | VAF 75/317 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MYO7A | c.1683G>C p.E561D | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- MYO7B | c.3380T>G p.L1127R | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAALADL1 | c.2215G>T p.D739Y | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); called by muse, mutect2
- NAV2 | c.824A>T p.Q275L | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NCAM1 | c.1919C>A p.S640Y (on ENST00000316851 / NM_181351.5; = p.S630Y on NM_000615.7) | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCAM1 | c.2100C>G p.F700L (on ENST00000316851 / NM_181351.5; = p.F690L on NM_000615.7) | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- NCAPG | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- NCKAP1L | c.1076C>A p.P359Q | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEIL2 | c.754C>G p.L252V | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NELL2 | c.1959G>T p.W653C | Missense Mutation (SNP) | VAF 126/357 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLGN1 | c.910del p.A304Lfs*25 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- NLRP8 | c.2753C>G p.S918C | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- NOA1 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NOD2 | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NRK | c.3376G>T p.D1126Y | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- NRP2 | c.433+2T>A p.X145_splice | Splice Site (SNP) | VAF 72/157 reads (46%) | called by muse, mutect2, varscan2
- NRXN1 | c.3556A>C p.K1186Q | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- NRXN2 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSD1 | c.4072C>T p.Q1358* | Nonsense Mutation (SNP) | VAF 85/154 reads (55%) | called by muse, mutect2, varscan2
- NUP107 | c.2707A>T p.K903* | Nonsense Mutation (SNP) | VAF 35/212 reads (17%) | called by muse, mutect2, varscan2
- NWD2 | c.3111C>G p.D1037E | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ODF2 | c.733G>T p.D245Y (on ENST00000434106 / NM_153433.2; = p.D221Y on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR10A7 | c.671C>A p.T224K | Missense Mutation (SNP) | VAF 39/389 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR10X1 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR11H7 | c.737T>A p.V246D | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- OR2M2 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 142/898 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2T8 | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, varscan2
- OR2W1 | c.857del p.N286Tfs*7 | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | called by mutect2, pindel, varscan2
- OR2W1 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 81/226 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR2W3 | c.814A>G p.M272V | Missense Mutation (SNP) | VAF 286/497 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR51B6 | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR52H1 | c.233C>A p.A78D (on ENST00000322653; = p.A84D on NM_001005289.1) | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR6C2 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 63/345 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- OR8I2 | c.492C>A p.S164R | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- OTOL1 | c.261T>G p.F87L | Missense Mutation (SNP) | VAF 60/380 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by mutect2, varscan2
- P2RY8 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 78/390 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PAFAH2 | c.282T>G p.F94L | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PAK5 | c.293A>T p.N98I | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAPPA | c.3666T>G p.N1222K | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- PARN | c.703A>G p.K235E | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PCDHA6 | c.1282_1283del p.R428Gfs*22 | Frame Shift Del (DEL) | VAF 198/599 reads (33%) | called by pindel, varscan2
- PCDHGB6 | c.718C>G p.P240A | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCSK5 | c.4070G>T p.C1357F | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- PDE6B | c.859T>C p.F287L | Missense Mutation (SNP) | VAF 181/504 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- PEG3 | c.2077G>A p.A693T | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PEX5L | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 37/459 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- PIP4P2 | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PKHD1 | c.10618G>T p.D3540Y | Missense Mutation (SNP) | VAF 137/426 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PLA2G3 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 133/354 reads (38%) | called by muse, mutect2, varscan2
- PLEC | c.3607G>C p.E1203Q (on ENST00000322810 / NM_201380.4; = p.E1093Q on NM_000445.5) | Missense Mutation (SNP) | VAF 81/682 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLXNB2 | c.5246A>T p.K1749M | Missense Mutation (SNP) | VAF 121/376 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POU3F4 | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- POU4F2 | c.394C>A p.H132N | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- PRAMEF18 | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 24/526 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); called by muse, mutect2
- PRKCI | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 716/814 reads (88%) | called by muse, mutect2, varscan2
- PRRC2A | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PSMB4 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 88/497 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PSPH | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 75/331 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PTPRD | c.4374A>C p.E1458D | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PTPRT | c.1789G>T p.D597Y | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- PXDN | c.933C>A p.D311E | Missense Mutation (SNP) | VAF 111/185 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PZP | c.4019C>A p.P1340Q | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- RASGRP3 | c.2012C>A p.T671K (on ENST00000402538 / NM_001349975.2; = p.T670K on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RAVER1 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RDH10 | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- REG4 | c.346A>T p.R116* | Nonsense Mutation (SNP) | VAF 158/378 reads (42%) | called by muse, mutect2, varscan2
- RELN | c.5012G>T p.G1671V | Missense Mutation (SNP) | VAF 185/402 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGS12 | c.3777G>T p.E1259D | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- RIN3 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- RNMT | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO3 | c.451del p.A151Qfs*71 | Frame Shift Del (DEL) | VAF 13/102 reads (13%) | called by mutect2, pindel
- RPS6KA2 | c.335T>C p.I112T | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RSPO2 | c.370T>G p.C124G | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RTTN | c.3841T>G p.S1281A | Missense Mutation (SNP) | VAF 111/467 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCIN | c.1677C>A p.S559R (on ENST00000297029 / NM_001112706.3; = p.S312R on NM_033128.3) | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SCN1A | c.2452A>C p.K818Q (on ENST00000303395 / NM_001202435.3; = p.K807Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMA3A | c.2128A>T p.I710F | Missense Mutation (SNP) | VAF 128/296 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SETD1B | c.3540G>C p.E1180D | Missense Mutation (SNP) | VAF 196/444 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SGO1 | c.1427G>C p.R476P (on ENST00000263753 / NM_001012410.5; = p.R207P on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHANK2 | c.4772C>A p.P1591H | Missense Mutation (SNP) | VAF 157/421 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SHC3 | c.1420T>A p.S474T | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SHMT2 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SHPRH | c.4438C>T p.Q1480* (on ENST00000275233 / NM_001042683.3; = p.Q1484* on NM_173082.3) | Nonsense Mutation (SNP) | VAF 41/244 reads (17%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.1160C>A p.P387Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC37A1 | c.1073-1G>C p.X358_splice | Splice Site (SNP) | VAF 6/103 reads (6%) | called by muse, mutect2
- SLC38A4 | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK3 | c.1823A>T p.E608V | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SMAP1 | c.784G>T p.A262S (on ENST00000370455 / NM_001044305.3; = p.A235S on NM_021940.5) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMCHD1 | c.3113G>T p.R1038I | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SNRPN | c.637A>T p.I213L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNTG1 | c.1534A>C p.K512Q | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SORBS2 | c.1250G>A p.S417N | Missense Mutation (SNP) | VAF 107/386 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPAG9 | c.2356A>G p.T786A (on ENST00000262013 / NM_001130528.3; = p.T772A on NM_003971.6) | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SPATA31A1 | c.1467C>A p.F489L | Missense Mutation (SNP) | VAF 115/711 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SPATA48 | c.524C>A p.P175Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2
- SPEF2 | c.1864C>A p.L622I | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SPEF2 | c.3959C>T p.P1320L | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- SPHKAP | c.3583T>C p.Y1195H | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRCAP | c.7072dup p.Q2358Pfs*12 | Frame Shift Ins (INS) | VAF 23/117 reads (20%) | called by mutect2, pindel
- ST18 | c.319A>T p.T107S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAB2 | c.437C>A p.A146D | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAT4 | c.96T>A p.H32Q | Missense Mutation (SNP) | VAF 109/370 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCHH | c.2242T>C p.W748R | Missense Mutation (SNP) | VAF 52/368 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFAP2D | c.900G>T p.L300F | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TG | c.6716C>G p.A2239G | Missense Mutation (SNP) | VAF 469/783 reads (60%) | SIFT tolerated (0.58); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TGFA | c.86C>A p.P29Q | Missense Mutation (SNP) | VAF 74/593 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- THY1 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 146/369 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.077); called by mutect2, varscan2
- TIMP2 | c.374C>A p.T125N | Missense Mutation (SNP) | VAF 158/440 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- TLE4 | c.1403C>A p.A468D | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TM9SF3 | c.1277T>G p.F426C | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- TMEM131 | c.5132G>A p.S1711N | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM132B | c.3028A>G p.K1010E | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- TMEM132C | c.336G>T p.L112F | Missense Mutation (SNP) | VAF 67/288 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- TMEM132E | c.1214T>G p.V405G (on ENST00000321639; = p.V495G on NM_001304438.2) | Missense Mutation (SNP) | VAF 43/310 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM176B | c.406T>A p.F136I | Missense Mutation (SNP) | VAF 162/449 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- TMEM209 | c.952G>C p.V318L | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TMUB2 | c.540C>A p.F180L (on ENST00000538716 / NM_001353177.2; = p.F160L on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2
- TNFRSF1A | c.1363A>T p.R455* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- TOMM34 | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TPBG | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TRAP1 | c.731C>A p.A244D | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- TRAV20 | c.201C>A p.F67L | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TREH | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRGV9 | c.56A>T p.Y19F | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- TRIM49 | c.97A>G p.S33G | Missense Mutation (SNP) | VAF 70/459 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TRIM64C | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 119/475 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM75P | c.1172A>T p.D391V | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- TRPM7 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPS1 | c.811G>T p.V271L (on ENST00000220888 / NM_001330599.2; = p.V284L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TSHZ2 | c.1151A>G p.E384G | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTC26 | c.1533C>G p.I511M | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TTLL6 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- TTN | c.33588G>A p.V11196= (on ENST00000591111; = p.V10269= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.28356C>A p.Y9452* (on ENST00000591111; = p.Y8525* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 98/288 reads (34%) | called by muse, mutect2, varscan2
- UBR5 | c.4684G>T p.D1562Y | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBXN11 | c.148A>C p.I50L | Missense Mutation (SNP) | VAF 65/319 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UNC5C | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 84/353 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC5D | c.2738G>C p.G913A | Missense Mutation (SNP) | VAF 97/495 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- VPS35L | c.1024-2A>T p.X342_splice | Splice Site (SNP) | VAF 49/184 reads (27%) | called by muse, mutect2, varscan2
- VSIG4 | c.1034G>C p.S345T | Missense Mutation (SNP) | VAF 84/161 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- WNK1 | c.6644-5A>T | Splice Region (SNP) | VAF 139/413 reads (34%) | called by muse, mutect2, varscan2
- WNK3 | c.4055C>A p.S1352Y | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- XYLT1 | c.2692A>G p.T898A | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ZDHHC2 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZFAT | c.3697G>A p.E1233K | Missense Mutation (SNP) | VAF 155/452 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, varscan2
- ZFAT | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 146/826 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, varscan2
- ZFAT | c.3232G>T p.E1078* | Nonsense Mutation (SNP) | VAF 30/181 reads (17%) | called by muse, mutect2, varscan2
- ZIC1 | c.939C>G p.F313L | Missense Mutation (SNP) | VAF 177/361 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZMIZ1 | c.792G>C p.M264I | Missense Mutation (SNP) | VAF 134/232 reads (58%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- ZNF107 | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF165 | c.877A>G p.K293E | Missense Mutation (SNP) | VAF 44/345 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF185 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF404 | c.1215T>A p.H405Q | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF442 | c.1107A>T p.R369S | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2
- ZNF532 | c.1848C>A p.Y616* | Nonsense Mutation (SNP) | VAF 37/197 reads (19%) | called by muse, mutect2, varscan2
- AADACL2 | c.828T>C p.H276= | Silent (SNP) | VAF 52/378 reads (14%) | called by muse, mutect2, varscan2
- ABCC5 | c.4041C>T p.H1347= | Silent (SNP) | VAF 32/300 reads (11%) | called by muse, mutect2
- ADAMTS16 | c.3663G>A p.K1221= | Silent (SNP) | VAF 110/397 reads (28%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.2493G>T p.T831= | Silent (SNP) | VAF 114/356 reads (32%) | called by muse, mutect2, varscan2
- ADGRL3 | c.1467A>G p.R489= (on ENST00000506720 / NM_001322402.2; = p.R421= on NM_015236.6) | Silent (SNP) | VAF 91/319 reads (29%) | called by muse, mutect2, varscan2
- AGT | c.270A>G p.L90= | Silent (SNP) | VAF 463/846 reads (55%) | called by muse, mutect2, varscan2
- AIFM3 | c.670C>T p.L224= | Silent (SNP) | VAF 69/450 reads (15%) | called by muse, mutect2, varscan2
- ANKS6 | c.1650G>T p.P550= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, varscan2
- ATP1A3 | c.837G>A p.G279= (on ENST00000545399 / NM_001256214.2; = p.G266= on NM_152296.5) | Silent (SNP) | VAF 128/312 reads (41%) | called by muse, mutect2, varscan2
- BACH1 | c.981C>T p.H327= | Silent (SNP) | VAF 50/237 reads (21%) | called by muse, mutect2, varscan2
- BRINP3 | c.2049G>T p.L683= | Silent (SNP) | VAF 126/253 reads (50%) | catalogued as COSV66515107; called by muse, mutect2, varscan2
- BRSK1 | c.309G>A p.K103= | Silent (SNP) | VAF 56/291 reads (19%) | called by muse, mutect2, varscan2
- C7 | c.1161C>A p.G387= | Silent (SNP) | VAF 54/239 reads (23%) | called by muse, mutect2, varscan2
- CACNA1I | c.5733T>C p.S1911= | Silent (SNP) | VAF 43/316 reads (14%) | called by muse, mutect2, varscan2
- CAMTA1 | c.2151C>T p.H717= | Silent (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- CCDC110 | c.1533A>T p.I511= | Silent (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- CCN2 | c.192G>A p.L64= | Silent (SNP) | VAF 91/502 reads (18%) | called by muse, mutect2, varscan2
- CDH18 | c.1698G>T p.L566= | Silent (SNP) | VAF 42/372 reads (11%) | called by muse, mutect2, varscan2
- CDH20 | c.2298C>A p.A766= | Silent (SNP) | VAF 46/198 reads (23%) | called by muse, mutect2, varscan2
- CDK17 | c.573C>G p.T191= | Silent (SNP) | VAF 13/156 reads (8%) | called by muse, mutect2
- CFAP54 | c.3435T>C p.Y1145= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- CNGA4 | c.1086G>C p.L362= | Silent (SNP) | VAF 38/184 reads (21%) | called by muse, mutect2, varscan2
- CSF2RB | c.219G>C p.V73= | Silent (SNP) | VAF 39/372 reads (10%) | called by muse, mutect2, varscan2
- CSMD3 | c.9294T>A p.A3098= (on ENST00000297405 / NM_001363185.1; = p.A2929= on NM_052900.3) | Silent (SNP) | VAF 92/455 reads (20%) | called by muse, mutect2, varscan2
- CUBN | c.544T>C p.L182= | Silent (SNP) | VAF 73/350 reads (21%) | catalogued as rs755414730; called by muse, mutect2, varscan2
- DGKB | c.1215G>A p.Q405= | Silent (SNP) | VAF 49/262 reads (19%) | called by muse, mutect2, varscan2
- DOK4 | c.9C>T p.T3= | Silent (SNP) | VAF 60/300 reads (20%) | catalogued as rs1473545103; called by muse, mutect2, varscan2
- DRD2 | c.58C>A p.R20= | Silent (SNP) | VAF 160/354 reads (45%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.11802G>A p.A3934= | Silent (SNP) | VAF 201/749 reads (27%) | catalogued as rs151307859; called by muse, mutect2, varscan2
- EN2 | c.228G>T p.R76= | Silent (SNP) | VAF 70/219 reads (32%) | catalogued as COSV99818593; called by muse, mutect2, varscan2
- FAM186A | c.6612G>A p.V2204= | Silent (SNP) | VAF 33/250 reads (13%) | called by muse, mutect2, varscan2
- FAM47A | c.1065C>A p.S355= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as rs779374074; called by muse, varscan2
- FCGBP | c.1761C>T p.V587= | Silent (SNP) | VAF 147/458 reads (32%) | called by muse, mutect2, varscan2
- FLRT2 | c.771C>G p.L257= | Silent (SNP) | VAF 32/335 reads (10%) | catalogued as rs764530673; called by muse, mutect2
- FRS3 | c.363C>T p.R121= | Silent (SNP) | VAF 12/277 reads (4%) | catalogued as rs1481554357; called by muse, mutect2
- FSTL5 | c.1941C>T p.C647= | Silent (SNP) | VAF 43/368 reads (12%) | catalogued as rs139415477; called by muse, mutect2, varscan2
- GAS2L2 | c.159C>T p.A53= | Silent (SNP) | VAF 38/368 reads (10%) | called by muse, mutect2, varscan2
- GASK1B | c.888C>T p.S296= | Silent (SNP) | VAF 247/851 reads (29%) | called by muse, mutect2, varscan2
- GCC2 | c.174C>G p.L58= | Silent (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- GIMAP8 | c.789A>G p.A263= | Silent (SNP) | VAF 61/413 reads (15%) | called by muse, mutect2, varscan2
- GLB1L2 | c.1845G>C p.T615= | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as COSV57000201; called by muse, mutect2, varscan2
- GLB1L3 | c.1035C>A p.T345= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs1428420975; called by muse, mutect2, varscan2
- GPD1L | c.1053A>G p.T351= | Silent (SNP) | VAF 112/312 reads (36%) | catalogued as rs1334490847; called by muse, mutect2, varscan2
- GPR148 | c.423C>T p.A141= | Silent (SNP) | VAF 61/448 reads (14%) | called by muse, mutect2, varscan2
- GRB7 | c.1234C>T p.L412= | Silent (SNP) | VAF 97/661 reads (15%) | called by muse, mutect2, varscan2
- GREB1L | c.5250T>C p.F1750= | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- GRIA3 | c.1584G>T p.L528= | Silent (SNP) | VAF 65/90 reads (72%) | catalogued as COSV99989701; called by muse, mutect2, varscan2
- GRM1 | c.996G>A p.V332= | Silent (SNP) | VAF 146/364 reads (40%) | catalogued as rs540911882; called by muse, mutect2, varscan2
- GTF3C1 | c.5169G>A p.E1723= | Silent (SNP) | VAF 84/385 reads (22%) | called by muse, mutect2, varscan2
- HMX2 | c.114C>T p.V38= | Silent (SNP) | VAF 159/278 reads (57%) | called by muse, mutect2, varscan2
- IFTAP | c.306A>T p.L102= | Silent (SNP) | VAF 72/188 reads (38%) | called by muse, mutect2, varscan2
- IGKV3D-7 | c.359C>A p.*120= | Silent (SNP) | VAF 78/830 reads (9%) | called by muse, mutect2
- IGKV5-2 | c.99G>C p.A33= | Silent (SNP) | VAF 220/293 reads (75%) | called by muse, mutect2, varscan2
- KCTD8 | c.15C>T p.D5= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- KHSRP | c.1548G>A p.G516= | Silent (SNP) | VAF 75/280 reads (27%) | called by muse, mutect2, varscan2
- KLHL12 | c.894G>C p.V298= | Silent (SNP) | VAF 44/368 reads (12%) | called by muse, mutect2, varscan2
- KLHL6 | c.1725G>C p.T575= | Silent (SNP) | VAF 17/424 reads (4%) | catalogued as rs1183080233, COSV58064936; called by muse, mutect2
- KRT4 | c.1440C>A p.S480= | Silent (SNP) | VAF 49/371 reads (13%) | catalogued as COSV99543252; called by muse, mutect2, varscan2
- LEXM | c.1155C>T p.L385= | Silent (SNP) | VAF 94/175 reads (54%) | called by muse, mutect2, varscan2
- LILRB3 | c.90C>A p.T30= | Silent (SNP) | VAF 104/252 reads (41%) | called by muse, mutect2, varscan2
- LRBA | c.2928G>T p.T976= | Silent (SNP) | VAF 64/156 reads (41%) | called by muse, mutect2, varscan2
- LRP2 | c.10056T>C p.D3352= | Silent (SNP) | VAF 57/372 reads (15%) | called by muse, mutect2, varscan2
- LRRN3 | c.990T>C p.F330= | Silent (SNP) | VAF 29/159 reads (18%) | called by muse, mutect2, varscan2
- MACF1 | c.6813C>T p.G2271= | Silent (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- MAPK8IP2 | c.1137G>A p.P379= | Silent (SNP) | VAF 104/253 reads (41%) | catalogued as rs571810591; called by muse, mutect2, varscan2
- MC2R | c.669C>T p.I223= | Silent (SNP) | VAF 143/388 reads (37%) | called by muse, mutect2, varscan2
- MCM9 | c.54G>C p.S18= | Silent (SNP) | VAF 41/185 reads (22%) | catalogued as COSV60163398; called by muse, mutect2, varscan2
- MED30 | c.81A>G p.E27= | Silent (SNP) | VAF 168/412 reads (41%) | catalogued as COSV52067343; called by muse, mutect2, varscan2
- METTL18 | c.879A>T p.S293= | Silent (SNP) | VAF 81/158 reads (51%) | called by muse, mutect2, varscan2
- METTL3 | c.654C>A p.A218= | Silent (SNP) | VAF 28/99 reads (28%) | called by muse, mutect2, varscan2
- MMS22L | c.618G>A p.P206= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs45568644; called by muse, mutect2, varscan2
- MOGAT3 | c.247C>A p.R83= | Silent (SNP) | VAF 195/458 reads (43%) | called by muse, mutect2, varscan2
- MST1R | c.1284G>T p.L428= | Silent (SNP) | VAF 174/277 reads (63%) | called by muse, mutect2, varscan2
- MUC16 | c.31818C>A p.T10606= | Silent (SNP) | VAF 44/158 reads (28%) | called by muse, mutect2, varscan2
- MYO16 | c.4725G>A p.P1575= | Silent (SNP) | VAF 21/32 reads (66%) | called by muse, mutect2, varscan2
- NADK2 | c.1150A>C p.R384= (on ENST00000381937 / NM_001085411.3; = p.R221= on NM_153013.4) | Silent (SNP) | VAF 48/280 reads (17%) | called by muse, mutect2, varscan2
- NAV3 | c.6225C>T p.T2075= (on ENST00000397909 / NM_001024383.2; = p.T2053= on NM_014903.6) | Silent (SNP) | VAF 16/234 reads (7%) | catalogued as COSV57102816; called by muse, mutect2
- NCAM1 | c.897C>A p.T299= | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2
- NDUFS1 | c.1398A>G p.L466= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- NEFM | c.147C>T p.S49= | Silent (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- NELL1 | c.2346G>A p.T782= | Silent (SNP) | VAF 69/201 reads (34%) | catalogued as rs369702287, COSV54270618; called by muse, mutect2, varscan2
- NID2 | c.2958T>C p.P986= | Silent (SNP) | VAF 41/251 reads (16%) | catalogued as rs768282300; called by muse, mutect2, varscan2
- NPAS4 | c.2217C>T p.A739= | Silent (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- NPFFR2 | c.1104C>A p.S368= | Silent (SNP) | VAF 90/303 reads (30%) | called by muse, mutect2, varscan2
- NPY2R | c.366G>T p.L122= | Silent (SNP) | VAF 48/192 reads (25%) | called by muse, mutect2, varscan2
- NRXN3 | c.735C>T p.S245= | Silent (SNP) | VAF 64/280 reads (23%) | catalogued as rs1263008583; called by muse, mutect2, varscan2
- NWD2 | c.2236C>T p.L746= | Silent (SNP) | VAF 38/159 reads (24%) | called by muse, mutect2, varscan2
- NYAP1 | c.2034G>A p.G678= | Silent (SNP) | VAF 133/315 reads (42%) | called by muse, mutect2, varscan2
- ODF2 | c.732G>T p.T244= (on ENST00000434106 / NM_153433.2; = p.T220= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 49/174 reads (28%) | called by muse, mutect2, varscan2
- OR4D10 | c.141C>T p.V47= | Silent (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- OR6S1 | c.366G>A p.A122= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as rs756983954, COSV57838027; called by muse, mutect2, varscan2
- OTUD7A | c.1707G>A p.E569= (on ENST00000307050 / NM_001382637.1; = p.E562= on NM_130901.3) | Silent (SNP) | VAF 38/156 reads (24%) | called by muse, mutect2, varscan2
- PC | c.288C>T p.Y96= | Silent (SNP) | VAF 86/406 reads (21%) | catalogued as rs1261547002; called by muse, varscan2
- PCDHB4 | c.786G>A p.R262= | Silent (SNP) | VAF 86/172 reads (50%) | catalogued as rs1199122007; called by muse, mutect2, varscan2
- PLA2G7 | c.54G>A p.V18= | Silent (SNP) | VAF 134/438 reads (31%) | called by muse, mutect2, varscan2
- PRLR | c.1434G>A p.E478= | Silent (SNP) | VAF 59/457 reads (13%) | catalogued as rs376661900; called by muse, mutect2, varscan2
- PRR23B | c.228C>T p.V76= | Silent (SNP) | VAF 31/271 reads (11%) | catalogued as rs1256424221, COSV100272062; called by muse, mutect2, varscan2
- PRUNE2 | c.1554A>G p.A518= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV65044175; called by muse, mutect2, varscan2
- PZP | c.4020A>C p.P1340= | Silent (SNP) | VAF 46/308 reads (15%) | called by muse, mutect2, varscan2
- RASEF | c.771A>G p.E257= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as rs1338507498; called by muse, mutect2, varscan2
- SFRP4 | c.726T>C p.S242= | Silent (SNP) | VAF 77/199 reads (39%) | called by muse, mutect2, varscan2
- SHOX | c.690G>A p.P230= | Silent (SNP) | VAF 125/765 reads (16%) | called by muse, mutect2, varscan2
- SLC10A2 | c.708G>C p.A236= | Silent (SNP) | VAF 172/298 reads (58%) | catalogued as COSV55360173; called by muse, mutect2, varscan2
- SLC10A7 | c.855G>A p.P285= | Silent (SNP) | VAF 15/354 reads (4%) | called by muse, mutect2
- SLC1A6 | c.519C>T p.P173= | Silent (SNP) | VAF 237/331 reads (72%) | catalogued as rs1246571315; called by muse, mutect2, varscan2
- SLC6A18 | c.1809G>T p.A603= | Silent (SNP) | VAF 321/1147 reads (28%) | catalogued as COSV57253659; called by muse, mutect2, varscan2
- SLC6A4 | c.1209C>T p.P403= | Silent (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- SRRM4 | c.138G>A p.E46= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as rs771380437; called by muse, mutect2, varscan2
- ST3GAL6 | c.228T>C p.Y76= | Silent (SNP) | VAF 45/232 reads (19%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.861G>A p.Q287= | Silent (SNP) | VAF 33/175 reads (19%) | catalogued as COSV100868172; called by muse, mutect2, varscan2
- STPG2 | c.240T>A p.P80= | Silent (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2
- TBC1D4 | c.2904G>A p.V968= | Silent (SNP) | VAF 71/256 reads (28%) | called by muse, mutect2, varscan2
- TG | c.4107A>G p.K1369= | Silent (SNP) | VAF 83/694 reads (12%) | called by muse, mutect2, varscan2
- TIAM2 | c.1146G>A p.R382= | Silent (SNP) | VAF 89/175 reads (51%) | catalogued as rs759237326; called by muse, mutect2, varscan2
- TLR2 | c.450A>G p.K150= | Silent (SNP) | VAF 40/157 reads (25%) | called by muse, mutect2, varscan2
- TMEM132D | c.1780C>T p.L594= | Silent (SNP) | VAF 143/378 reads (38%) | catalogued as COSV67159685; called by muse, mutect2, varscan2
- TMEM70 | c.144G>T p.P48= | Silent (SNP) | VAF 53/250 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.29835C>T p.T9945= (on ENST00000591111; = p.T9018= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- UGT2A3 | c.459C>A p.P153= | Silent (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
- VPS9D1 | c.1176G>T p.R392= | Silent (SNP) | VAF 120/169 reads (71%) | called by muse, mutect2, varscan2
- VWA7 | c.1563G>T p.V521= | Silent (SNP) | VAF 77/228 reads (34%) | catalogued as COSV65172332, COSV65174087; called by muse, mutect2, varscan2
- WAC | c.1497A>T p.V499= | Silent (SNP) | VAF 38/181 reads (21%) | called by muse, mutect2, varscan2
- WDFY3 | c.7585C>T p.L2529= | Silent (SNP) | VAF 58/161 reads (36%) | called by muse, mutect2, varscan2
- WDFY4 | c.6G>A p.E2= | Silent (SNP) | VAF 67/135 reads (50%) | called by muse, mutect2, varscan2
- WDR3 | c.645G>C p.L215= | Silent (SNP) | VAF 63/324 reads (19%) | catalogued as COSV62523840; called by muse, mutect2, varscan2
- WDR7 | c.459A>G p.V153= | Silent (SNP) | VAF 37/131 reads (28%) | called by muse, mutect2, varscan2
- WNT3 | c.636G>T p.S212= | Silent (SNP) | VAF 39/212 reads (18%) | catalogued as rs1422054724, COSV56646118; called by muse, mutect2, varscan2
- ZAN | c.4758C>T p.T1586= | Silent (SNP) | VAF 244/580 reads (42%) | called by muse, mutect2, varscan2
- ZFP36L2 | c.924G>T p.S308= | Silent (SNP) | VAF 212/342 reads (62%) | called by muse, mutect2, varscan2
- ZNF132 | c.204G>A p.L68= | Silent (SNP) | VAF 40/203 reads (20%) | called by muse, mutect2, varscan2
- ZNF169 | c.1332C>T p.T444= | Silent (SNP) | VAF 56/331 reads (17%) | called by muse, mutect2, varscan2
- ZNF418 | c.325C>T p.L109= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as rs375536083; called by muse, mutect2, varscan2
- ZNF608 | c.2206C>A p.R736= | Silent (SNP) | VAF 101/185 reads (55%) | called by muse, mutect2, varscan2
- ZNF804B | c.822C>T p.H274= | Silent (SNP) | VAF 115/309 reads (37%) | catalogued as COSV100302939; called by muse, mutect2, varscan2
- AC139769.1 | n.214-4410A>T | Intron (SNP) | VAF 24/173 reads (14%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9880C>A | Intron (SNP) | VAF 58/106 reads (55%) | catalogued as rs771508863; called by muse, mutect2, varscan2
- ACSS3 | c.1354+215G>T | Intron (SNP) | VAF 52/271 reads (19%) | called by muse, mutect2, varscan2
- ADGRD1 | c.966+1841C>A | Intron (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- AF186192.2 | chr8:144698853 G>C | 5'Flank (SNP) | VAF 40/404 reads (10%) | called by muse, mutect2
- AGRN | c.3517-43G>A | Intron (SNP) | VAF 77/244 reads (32%) | catalogued as rs769409270; called by muse, mutect2, varscan2
- BCLAF3 | c.1951-690G>T | Intron (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- C7orf61 | c.64-99C>T | Intron (SNP) | VAF 24/482 reads (5%) | called by muse, mutect2
- CA1 | c.235+102C>G | Intron (SNP) | VAF 62/331 reads (19%) | called by muse, varscan2
- CA2 | c.*38G>T | 3'UTR (SNP) | VAF 111/268 reads (41%) | catalogued as COSV53405646, COSV99570297; called by muse, mutect2, varscan2
- CEP295 | chr11:93732015 G>C | 3'Flank (SNP) | VAF 33/116 reads (28%) | called by muse, mutect2, varscan2
- COG5 | c.-33G>A | 5'UTR (SNP) | VAF 145/1081 reads (13%) | catalogued as rs1198021644; called by muse, mutect2, varscan2
- DCHS2 | n.4372G>A | RNA (SNP) | VAF 66/196 reads (34%) | called by muse, mutect2, varscan2
- DCX | c.-22-410G>A | Intron (SNP) | VAF 82/375 reads (22%) | called by muse, mutect2, varscan2
- DOCK7 | c.5493+90C>T | Intron (SNP) | VAF 27/134 reads (20%) | catalogued as rs768611132, COSV52017458; called by muse, mutect2, varscan2
- DPP6 | c.*271del | 3'UTR (DEL) | VAF 56/140 reads (40%) | called by mutect2, pindel, varscan2
- DTNBP1 | c.56+2408G>T | Intron (SNP) | VAF 75/544 reads (14%) | catalogued as rs1169294676; called by muse, mutect2, varscan2
- ESPNP | n.247C>A | RNA (SNP) | VAF 142/619 reads (23%) | called by muse, mutect2, varscan2
- FAAP100 | c.1404-212G>T | Intron (SNP) | VAF 170/408 reads (42%) | called by muse, mutect2, varscan2
- FAM135B | c.77+528G>A | Intron (SNP) | VAF 26/281 reads (9%) | called by muse, mutect2
- FAM182A | n.1013G>T | RNA (SNP) | VAF 83/511 reads (16%) | called by muse, varscan2
- FAM182A | n.1014G>T | RNA (SNP) | VAF 85/506 reads (17%) | catalogued as rs765605041; called by muse, varscan2
- FAS | c.*107G>A | 3'UTR (SNP) | VAF 166/343 reads (48%) | catalogued as COSV58240073; called by muse, mutect2, varscan2
- FBXL7 | c.740-1190G>A | Intron (SNP) | VAF 112/257 reads (44%) | called by muse, varscan2
- GNAO1 | c.723+7001G>A | Intron (SNP) | VAF 150/440 reads (34%) | catalogued as rs749685192; called by muse, mutect2, varscan2
- GRAMD2B | c.128+11024G>C | Intron (SNP) | VAF 70/151 reads (46%) | called by muse, mutect2, varscan2
- GRIK1 | c.1207-1085T>A | Intron (SNP) | VAF 21/108 reads (19%) | called by muse, mutect2, varscan2
- GRIN2A | c.1007+32G>A | Intron (SNP) | VAF 49/242 reads (20%) | called by muse, mutect2, varscan2
- HADH | c.*39C>T | 3'UTR (SNP) | VAF 41/373 reads (11%) | catalogued as rs777124537; called by muse, mutect2, varscan2
- HERC2P3 | n.1410C>T | RNA (SNP) | VAF 82/775 reads (11%) | called by muse, varscan2
- HNF1A | c.1623+16G>A | Intron (SNP) | VAF 199/474 reads (42%) | catalogued as rs1555212572; ClinVar: likely benign; called by muse, mutect2, varscan2
- HNMT | c.190+11108T>C | Intron (SNP) | VAF 44/360 reads (12%) | called by muse, mutect2, varscan2
- HOATZ | chr11:111512947 ins TGTAGGCAG | 5'Flank (INS) | VAF 54/294 reads (18%) | called by mutect2, varscan2
- HOXA7 | chr7:27152974 A>G | 3'Flank (SNP) | VAF 48/188 reads (26%) | catalogued as rs1163497437; called by muse, mutect2, varscan2
- HSP90AA4P | n.297C>A | RNA (SNP) | VAF 12/172 reads (7%) | catalogued as rs1233103722; called by muse, mutect2
- IDUA | c.*51G>T | 3'UTR (SNP) | VAF 95/294 reads (32%) | called by muse, mutect2, varscan2
- IGHV1-46 | c.-11A>C | 5'UTR (SNP) | VAF 32/293 reads (11%) | called by muse, mutect2, varscan2
- LINC01567 | n.79C>T | RNA (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- LINC01591 | n.615T>A | RNA (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- LRP10 | c.*1719C>T | 3'UTR (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+457G>A | Intron (SNP) | VAF 11/146 reads (8%) | called by muse, mutect2
- MRRFP1 | n.707G>T | RNA (SNP) | VAF 58/227 reads (26%) | called by muse, mutect2, varscan2
- MS4A4A | c.41+2019_41+2026del | Intron (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- NCAM1 | c.2131+2572C>A | Intron (SNP) | VAF 42/249 reads (17%) | catalogued as COSV57526129; called by muse, mutect2, varscan2
- NCF1B | n.249_250insA | RNA (INS) | VAF 154/718 reads (21%) | called by pindel, varscan2
- NDUFS2 | c.702+36dup | Intron (INS) | VAF 86/581 reads (15%) | called by mutect2, pindel, varscan2
- NF1 | c.7870-11C>A | Intron (SNP) | VAF 122/417 reads (29%) | called by muse, mutect2, varscan2
- NXPH3 | c.*2379C>T | 3'UTR (SNP) | VAF 65/461 reads (14%) | called by muse, mutect2, varscan2
- OPRM1 | c.1165-10669A>C | Intron (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.424-65807G>C | Intron (SNP) | VAF 68/488 reads (14%) | catalogued as rs950972437; called by muse, mutect2, varscan2
- POLR1E | chr9:37486106 G>A | 5'Flank (SNP) | VAF 38/155 reads (25%) | called by muse, mutect2, varscan2
- POM121L4P | n.1449G>T | RNA (SNP) | VAF 116/657 reads (18%) | called by muse, mutect2, varscan2
- POMT2 | c.*13G>A | 3'UTR (SNP) | VAF 158/638 reads (25%) | called by muse, mutect2, varscan2
- PPP1CC | c.*904G>A | 3'UTR (SNP) | VAF 51/213 reads (24%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2757+775C>A | Intron (SNP) | VAF 37/374 reads (10%) | called by muse, mutect2, varscan2
- PRB3 | c.604+23A>G | Intron (SNP) | VAF 66/446 reads (15%) | called by muse, varscan2
- RAD51D | c.*575del | 3'UTR (DEL) | VAF 139/491 reads (28%) | called by mutect2, pindel, varscan2
- RALYL | c.257-68559C>T | Intron (SNP) | VAF 40/102 reads (39%) | called by muse, mutect2, varscan2
- RASGEF1C | c.*32G>T | 3'UTR (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- RHOT2 | c.222+63G>T | Intron (SNP) | VAF 40/100 reads (40%) | called by muse, mutect2, varscan2
- RNF216 | c.874-185C>T | Intron (SNP) | VAF 27/164 reads (16%) | called by muse, mutect2, varscan2
- SIK2 | c.-15G>A | 5'UTR (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- SLC25A23 | c.483+435G>T | Intron (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- SLC47A1P2 | n.189G>A | RNA (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- SP5 | chr2:170714132 G>A | 5'Flank (SNP) | VAF 132/416 reads (32%) | called by muse, mutect2, varscan2
- SPACA6 | chr19:51692641 G>T | 5'Flank (SNP) | VAF 46/168 reads (27%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2483C>T | RNA (SNP) | VAF 157/802 reads (20%) | called by muse, mutect2, varscan2
- SSPOP | n.7712G>A | RNA (SNP) | VAF 77/449 reads (17%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.236+8134G>A | Intron (SNP) | VAF 51/202 reads (25%) | called by muse, varscan2
- TCN2 | c.65-580C>T | Intron (SNP) | VAF 19/110 reads (17%) | catalogued as rs1203549376; called by muse, mutect2, varscan2
- TJP2 | c.61-7296T>G | Intron (SNP) | VAF 47/191 reads (25%) | called by muse, mutect2, varscan2
- TK2 | c.31+267dup | Intron (INS) | VAF 66/463 reads (14%) | called by mutect2, pindel, varscan2
- TMEM135 | c.*6018C>A | 3'UTR (SNP) | VAF 35/152 reads (23%) | called by muse, mutect2, varscan2
- TMEM260 | chr14:56650101 G>T | 3'Flank (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- TRIM27 | c.920-289C>T | Intron (SNP) | VAF 24/172 reads (14%) | called by muse, mutect2, varscan2
- UBE3D | c.*49G>T | 3'UTR (SNP) | VAF 141/344 reads (41%) | called by muse, mutect2, varscan2
- Z96074.1 | n.151+3033C>T | Intron (SNP) | VAF 22/102 reads (22%) | catalogued as COSV65448299; called by muse, mutect2, varscan2
- ZEB1 | c.-102G>A | 5'UTR (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3325+3726G>T | Intron (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- ZNF251 | c.-142C>T | 5'UTR (SNP) | VAF 29/541 reads (5%) | called by muse, mutect2
- ZNF467 | chr7:149777290 C>T | 5'Flank (SNP) | VAF 49/267 reads (18%) | called by muse, mutect2, varscan2
- ZNF812P | n.823G>T | RNA (SNP) | VAF 41/134 reads (31%) | called by muse, mutect2, varscan2
